Somatic mutation profile of tumor specimen TCGA-CJ-4900-01A (aliquot TCGA-CJ-4900-01A-01D-1462-08) from TCGA case TCGA-CJ-4900, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 69.8 years (25,508 days).
Specimen TCGA-CJ-4900-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e2bd019-01b0-4862-b3b8-2eb4787a6eaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4900-11A (Solid Tissue Normal), aliquot TCGA-CJ-4900-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8acaa725-6121-4f6d-8397-93b6e01fc66f

The open-access MAF lists 41 somatic variants for this specimen: 36 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 29, Silent 5, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913346, CM164440, CM941379, COSV56543253, COSV56550270, COSV56558440, COSV56563690; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRINP2 | c.1970C>G p.S657C | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.431); catalogued as COSV64174848, COSV64179792; called by muse, mutect2, varscan2
- CACNA2D4 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54944209; called by muse, mutect2, varscan2
- CPXM2 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368753397; called by muse, mutect2, varscan2
- DDX46 | c.614A>T p.D205V | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV62798336; called by muse, varscan2
- DOCK6 | c.4952C>T p.S1651L | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV53910707; called by muse, mutect2
- FRY | c.6662T>C p.L2221S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV66564602; called by muse, mutect2, varscan2
- HORMAD2 | c.530A>C p.N177T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV60897210; called by muse, mutect2, varscan2
- HSPB2 | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV57051152; called by muse, mutect2, varscan2
- HUWE1 | c.6625A>G p.M2209V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV53333572; called by mutect2, varscan2
- ITPR3 | c.802A>G p.T268A | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65405284; called by muse, mutect2, varscan2
- KCND2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377746178, COSV58567964; called by muse, mutect2
- KIF5B | c.1395G>C p.R465S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.206); catalogued as COSV56650500; called by muse, mutect2, varscan2
- MGAM | c.3596C>T p.P1199L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV72073527; called by muse, mutect2
- MTUS2 | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV70912675; called by muse, mutect2
- MYH4 | c.206C>G p.T69S | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55111597; called by muse, mutect2, varscan2
- NAMPT | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV55994016; called by muse, varscan2
- OR8D2 | c.503T>G p.F168C | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62487996; called by muse, mutect2, varscan2
- PGBD4 | c.1354T>C p.Y452H | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56626405; called by muse, mutect2
- PLEKHM1 | c.1878G>C p.K626N | Missense Mutation (SNP) | VAF 3/57 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV69598487; called by muse, mutect2
- RABEP1 | c.1585C>T p.L529F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52582505; called by muse, mutect2, varscan2
- REG4 | c.303G>C p.K101N | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56652038; called by muse, mutect2, varscan2
- SPAM1 | c.1465C>A p.L489I | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs775926758, COSV56141054; called by muse, mutect2, varscan2
- SPON1 | c.422C>A p.T141N | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.117); catalogued as COSV59957267; called by muse, mutect2, varscan2
- TENM1 | c.2464T>C p.C822R | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64424379; called by muse, mutect2, varscan2
- THRSP | c.26C>G p.P9R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.997); catalogued as COSV99806421, COSV99806554; called by muse, mutect2, varscan2
- TMEM45B | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs369904524; called by muse, mutect2, varscan2
- UNC5B | c.1905T>A p.F635L | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV58974054; called by muse, mutect2
- VANGL2 | c.1382C>T p.T461I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV63603947; called by muse, mutect2, varscan2
- ZBTB41 | c.437C>A p.S146* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as COSV66358591; called by muse, mutect2, varscan2
- ZNF155 | c.1602del p.L535* | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs758512074; called by mutect2, varscan2
- ZNF45 | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 5/75 reads (7%) | catalogued as COSV54192319; called by muse, mutect2
- GTPBP10 | c.1069_1077del p.K357_L359del | In Frame Del (DEL) | VAF 26/168 reads (15%) | called by mutect2, varscan2
- PBRM1 | c.359_360del p.F120* | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, varscan2
- SESN2 | c.1350dup p.E451Rfs*213 | Frame Shift Ins (INS) | VAF 13/63 reads (21%) | called by mutect2, varscan2
- TECTA | c.4470_4476del p.G1491Afs*72 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- C1orf141 | c.516G>A p.L172= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV63992011; called by muse, mutect2, varscan2
- EEF1A2 | c.138G>A p.A46= | Silent (SNP) | VAF 35/176 reads (20%) | catalogued as rs1212477042, COSV53204582; ClinVar: likely benign; called by muse, mutect2, varscan2
- MGAT4C | c.978G>A p.K326= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as rs1448527931, COSV59829520, COSV59838193; called by muse, mutect2, varscan2
- PPL | c.3495C>T p.N1165= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as rs148525665; called by muse, mutect2, varscan2
- ZSWIM4 | c.2652C>T p.R884= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as rs757619341, COSV54319040; called by muse, mutect2, varscan2
